Somatic mutation profile of tumor specimen 0DUUQ0 from CCDI case PBCLBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,602 days).
Specimen 0DUUQ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 336e4ecf-3b9e-407b-bddb-440686ca9648.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd3a5e16-f06a-49fd-bcad-2219104392f6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NKX3-1 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 104/866 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101082744; called by muse, mutect2, varscan2
- CELSR1 | c.1917C>G p.I639M | Missense Mutation (SNP) | VAF 166/648 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
